Somatic mutation profile of tumor specimen MMRF_2736_1_BM_CD138pos (aliquot MMRF_2736_1_BM_CD138pos_T1_KHS5U_L14883) from MMRF case MMRF_2736, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.0 years (21,916 days).
Specimen MMRF_2736_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bfd34e30-8b3c-4c75-a6f7-05c469410c1e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2736_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2736_1_PB_WBC_C2_KHS5U_L14884; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbffe871-be20-4086-ae3a-3fddada16927

The open-access MAF lists 114 somatic variants for this specimen: 45 protein-altering or splice-affecting, 21 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, 3'UTR 22, Silent 21, Intron 13, 5'UTR 5, Splice Site 3, RNA 3, 3'Flank 3, Nonsense Mutation 3, 5'Flank 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANAPC2 | c.1493C>T p.S498L | Missense Mutation (SNP) | VAF 31/251 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); catalogued as rs201454359, COSV60568664; called by muse, mutect2, varscan2
- ARID1B | c.5140G>A p.D1714N | Missense Mutation (SNP) | VAF 46/215 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.076); catalogued as rs771781497; called by muse, mutect2, varscan2
- CCDC150 | c.841A>C p.K281Q | Missense Mutation (SNP) | VAF 78/165 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745935158, COSV55872506; called by mutect2, varscan2
- CCDC74A | c.250+1G>A p.X84_splice | Splice Site (SNP) | VAF 26/81 reads (32%) | catalogued as rs776346804; called by muse, mutect2, varscan2
- CNTN5 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 56/246 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as rs750514717; called by muse, mutect2, varscan2
- DHRS12 | c.757C>T p.R253C (on ENST00000444610 / NM_001377930.1; = p.R204C on NM_024705.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); catalogued as rs754822484; called by muse, mutect2, varscan2
- HEATR1 | c.3188C>G p.T1063S | Missense Mutation (SNP) | VAF 55/225 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV63983541; called by muse, mutect2, varscan2
- HES2 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100913916; called by muse, mutect2, varscan2
- IFIT5 | c.55C>T p.H19Y | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as rs1310055969; called by muse, mutect2, varscan2
- IGLV1-47 | c.165G>A p.W55* | Nonsense Mutation (SNP) | VAF 166/359 reads (46%) | catalogued as rs368080216; called by muse, mutect2, varscan2
- KCNB2 | c.2092G>A p.D698N | Missense Mutation (SNP) | VAF 76/182 reads (42%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.061); catalogued as rs751298935; called by muse, mutect2, varscan2
- KRTAP21-1 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.046); catalogued as COSV58646563; called by muse, mutect2, varscan2
- MAGI3 | c.3481G>A p.E1161K | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.52); catalogued as COSV99048817; called by muse, mutect2, varscan2
- NELL2 | c.1294C>T p.R432* | Nonsense Mutation (SNP) | VAF 145/369 reads (39%) | catalogued as rs1356454796, COSV61572282; called by muse, mutect2, varscan2
- NPY5R | c.192G>C p.M64I | Missense Mutation (SNP) | VAF 152/368 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58450828; called by muse, mutect2, varscan2
- NSMF | c.704+1G>A p.X235_splice | Splice Site (SNP) | VAF 38/103 reads (37%) | catalogued as rs761831367, COSV53009898; called by muse, mutect2, varscan2
- NUP210L | c.2468C>T p.S823F | Missense Mutation (SNP) | VAF 100/245 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV55157764; called by muse, mutect2, varscan2
- PDE6C | c.1670G>A p.R557Q | Missense Mutation (SNP) | VAF 106/232 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201309785; called by muse, mutect2, varscan2
- RNF175 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 103/287 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs200984268; called by muse, mutect2, varscan2
- ULBP1 | c.289G>C p.V97L | Missense Mutation (SNP) | VAF 73/169 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.1); catalogued as COSV57663388; called by muse, mutect2, varscan2
- XIRP1 | c.1516G>A p.G506R | Missense Mutation (SNP) | VAF 73/261 reads (28%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.953); catalogued as rs754048637, COSV61141619; called by muse, mutect2, varscan2
- YIPF2 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 91/224 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as rs764066952; called by muse, varscan2
- ADCY10 | c.4681T>C p.Y1561H | Missense Mutation (SNP) | VAF 137/316 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ARHGAP35 | c.1820G>C p.G607A | Missense Mutation (SNP) | VAF 102/282 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CASP7 | c.845T>G p.F282C | Missense Mutation (SNP) | VAF 182/439 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- CHD8 | c.1309_1311del p.A437del (on ENST00000646647 / NM_001170629.2; = p.A158del on NM_020920.4) | In Frame Del (DEL) | VAF 44/111 reads (40%) | called by mutect2, pindel, varscan2
- DEGS1 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGLV1-44 | c.35C>T p.T12I | Missense Mutation (SNP) | VAF 69/152 reads (45%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IGLV5-45 | c.136G>A p.G46S | Missense Mutation (SNP) | VAF 125/267 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- LYPD3 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 70/193 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAPK8IP2 | c.1183C>A p.Q395K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MTMR3 | c.3337-2A>G p.X1113_splice | Splice Site (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- NQO1 | c.752A>C p.K251T | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- OR2A42 | c.523del p.H175Tfs*51 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | called by mutect2, pindel, varscan2
- OR4S1 | c.874G>A p.V292M | Missense Mutation (SNP) | VAF 187/422 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- OR8J3 | c.373G>C p.A125P | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PCLO | c.3657dup p.L1220Tfs*4 | Frame Shift Ins (INS) | VAF 69/190 reads (36%) | called by mutect2, varscan2
- PRAG1 | c.3370T>G p.F1124V | Missense Mutation (SNP) | VAF 59/145 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- RNF144A | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 61/217 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SDHAF1 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC22A5 | c.886A>G p.I296V | Missense Mutation (SNP) | VAF 75/235 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- SPATA31D1 | c.1651C>T p.Q551* | Nonsense Mutation (SNP) | VAF 21/119 reads (18%) | called by muse, mutect2, varscan2
- TNPO1 | c.199T>G p.S67A | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.011); called by muse, mutect2
- XIRP1 | c.1033C>G p.Q345E | Missense Mutation (SNP) | VAF 68/243 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ZNF561 | c.1313T>C p.V438A | Missense Mutation (SNP) | VAF 222/558 reads (40%) | SIFT tolerated (0.76); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- ADGRF4 | c.1008C>T p.F336= | Silent (SNP) | VAF 62/157 reads (39%) | catalogued as rs747115069, COSV51956851; called by muse, mutect2, varscan2
- ADGRG4 | c.8586T>A p.A2862= | Silent (SNP) | VAF 120/283 reads (42%) | called by muse, mutect2, varscan2
- ADIPOQ | c.240C>T p.I80= | Silent (SNP) | VAF 70/127 reads (55%) | catalogued as rs200363536, COSV57858795; called by muse, mutect2, varscan2
- ATP9A | c.2322G>A p.E774= | Silent (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- CACNA1S | c.951C>A p.L317= | Silent (SNP) | VAF 37/133 reads (28%) | called by muse, mutect2, varscan2
- CKAP5 | c.4422T>A p.P1474= | Silent (SNP) | VAF 56/127 reads (44%) | called by muse, mutect2, varscan2
- CNTN1 | c.630C>T p.S210= | Silent (SNP) | VAF 104/277 reads (38%) | called by muse, mutect2, varscan2
- GRIK4 | c.699A>G p.E233= | Silent (SNP) | VAF 47/133 reads (35%) | called by muse, mutect2, varscan2
- H2AC17 | c.166C>T p.L56= | Silent (SNP) | VAF 57/121 reads (47%) | catalogued as rs570205272; called by muse, mutect2, varscan2
- IFFO2 | c.234C>T p.N78= | Silent (SNP) | VAF 85/204 reads (42%) | catalogued as rs1450057451; called by muse, mutect2, varscan2
- IGHJ4 | c.30G>A p.L10= | Silent (SNP) | VAF 37/68 reads (54%) | catalogued as rs782198992; called by muse, mutect2, varscan2
- IGLV3-16 | c.189G>C p.V63= | Silent (SNP) | VAF 79/106 reads (75%) | catalogued as rs375149658; called by muse, mutect2, varscan2
- LAMP5 | c.255C>T p.A85= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as rs915499868; called by muse, mutect2, varscan2
- NTAN1 | c.6G>A p.P2= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs1455114302; called by muse, mutect2, varscan2
- PEX6 | c.75C>T p.P25= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1189384100; called by muse, mutect2, varscan2
- PRKCG | c.1572G>A p.P524= | Silent (SNP) | VAF 37/77 reads (48%) | catalogued as rs760092806, COSV54723097; called by muse, mutect2, varscan2
- RPS6KB1 | c.294T>G p.G98= | Silent (SNP) | VAF 241/597 reads (40%) | called by muse, mutect2, varscan2
- SPATS2 | c.861G>A p.A287= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as rs147628927; called by muse, mutect2, varscan2
- SYCE1L | c.606C>T p.F202= | Silent (SNP) | VAF 35/40 reads (88%) | catalogued as rs1026941581; called by muse, mutect2, varscan2
- TIMM29 | c.249C>T p.F83= | Silent (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2
- ZNF454 | c.615A>G p.A205= | Silent (SNP) | VAF 117/184 reads (64%) | catalogued as COSV100194970; called by muse, mutect2, varscan2
- AC139795.1 | n.519C>A | RNA (SNP) | VAF 17/96 reads (18%) | called by muse, mutect2, varscan2
- ALS2CL | c.1437-153G>A | Intron (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122020975 T>G | 5'Flank (SNP) | VAF 84/183 reads (46%) | catalogued as rs746553168; called by muse, mutect2, varscan2
- BCL7A | chr12:122021402 C>T | 5'Flank (SNP) | VAF 62/190 reads (33%) | catalogued as rs925835724, COSV55846299, COSV55846759, COSV55847493; called by muse, mutect2, varscan2
- BICD2 | c.2469+518T>C | Intron (SNP) | VAF 105/408 reads (26%) | called by muse, mutect2, varscan2
- C18orf54 | c.*2005A>G | 3'UTR (SNP) | VAF 30/86 reads (35%) | called by muse, mutect2, varscan2
- CDH6 | c.*133A>G | 3'UTR (SNP) | VAF 17/97 reads (18%) | called by muse, mutect2, varscan2
- CFHR3 | c.614-9T>A | Intron (SNP) | VAF 73/195 reads (37%) | catalogued as rs1251402115; called by muse, mutect2, varscan2
- FAM86C2P | n.891T>A | RNA (SNP) | VAF 30/66 reads (45%) | called by muse, mutect2, varscan2
- FCRL5 | c.1681+225T>A | Intron (SNP) | VAF 111/245 reads (45%) | called by muse, mutect2, varscan2
- GAPVD1 | chr9:125366265 C>T | 3'Flank (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- GRIN3A | c.*1692A>G | 3'UTR (SNP) | VAF 36/161 reads (22%) | called by muse, mutect2, varscan2
- H4C11 | c.-4C>G | 5'UTR (SNP) | VAF 78/208 reads (38%) | called by muse, mutect2, varscan2
- ID3 | c.301-45C>T | Intron (SNP) | VAF 92/224 reads (41%) | called by muse, mutect2, varscan2
- IFNA4 | c.*98C>G | 3'UTR (SNP) | VAF 235/419 reads (56%) | catalogued as rs918712706; called by muse, mutect2, varscan2
- KALRN | c.4929+22798G>A | Intron (SNP) | VAF 33/182 reads (18%) | called by muse, mutect2, varscan2
- KCNH7 | c.-85G>A | 5'UTR (SNP) | VAF 55/175 reads (31%) | called by muse, mutect2, varscan2
- LILRB3 | c.34+25G>T | Intron (SNP) | VAF 67/293 reads (23%) | called by muse, mutect2, varscan2
- LYNX1 | c.*1012del | 3'UTR (DEL) | VAF 6/25 reads (24%) | catalogued as rs1289170675; called by mutect2, pindel
- MDFIC | c.*1456C>G | 3'UTR (SNP) | VAF 20/83 reads (24%) | called by muse, mutect2, varscan2
- MOXD1 | c.264+10453T>C | Intron (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- NEK6 | c.*1086G>T | 3'UTR (SNP) | VAF 29/208 reads (14%) | called by muse, mutect2, varscan2
- PDGFC | c.*241T>C | 3'UTR (SNP) | VAF 35/89 reads (39%) | called by muse, mutect2, varscan2
- PI15 | c.*190A>G | 3'UTR (SNP) | VAF 22/103 reads (21%) | called by muse, mutect2, varscan2
- PRKAA2 | c.*2789T>A | 3'UTR (SNP) | VAF 18/59 reads (31%) | called by muse, mutect2, varscan2
- PTPRM | c.*690G>A | 3'UTR (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2, varscan2
- RAB17 | c.*284C>T | 3'UTR (SNP) | VAF 43/136 reads (32%) | called by muse, mutect2, varscan2
- RIC8A | c.1065+48T>A | Intron (SNP) | VAF 63/153 reads (41%) | called by muse, mutect2, varscan2
- RPAP3 | c.*165G>C | 3'UTR (SNP) | VAF 23/66 reads (35%) | called by muse, mutect2, varscan2
- RPH3AL | c.*1G>A | 3'UTR (SNP) | VAF 50/110 reads (45%) | called by muse, mutect2, varscan2
- SAMD5 | c.*294C>T | 3'UTR (SNP) | VAF 37/79 reads (47%) | catalogued as rs758104662; called by muse, mutect2, varscan2
- SIM1 | chr6:100385307 A>G | 3'Flank (SNP) | VAF 45/102 reads (44%) | called by muse, mutect2, varscan2
- SIX1 | c.*1928G>A | 3'UTR (SNP) | VAF 26/59 reads (44%) | called by muse, mutect2, varscan2
- SLC39A4 | c.193-23T>C | Intron (SNP) | VAF 55/135 reads (41%) | called by muse, mutect2, varscan2
- SLC41A3 | c.273+436C>T | Intron (SNP) | VAF 6/46 reads (13%) | catalogued as rs776109306; called by muse, mutect2, varscan2
- SLN | c.*419A>G | 3'UTR (SNP) | VAF 23/70 reads (33%) | called by muse, mutect2, varscan2
- SPATA31D5P | n.2271A>G | RNA (SNP) | VAF 34/140 reads (24%) | called by mutect2, varscan2
- SRGAP3 | c.*844A>G | 3'UTR (SNP) | VAF 56/191 reads (29%) | called by muse, mutect2, varscan2
- TIMM29 | c.*15C>T | 3'UTR (SNP) | VAF 14/50 reads (28%) | catalogued as rs1398433925; called by muse, mutect2, varscan2
- TMEM184C | c.-366C>T | 5'UTR (SNP) | VAF 27/76 reads (36%) | called by muse, mutect2, varscan2
- TMEM196 | c.-746C>T | 5'UTR (SNP) | VAF 34/124 reads (27%) | catalogued as rs1236704310; called by muse, mutect2, varscan2
- TMOD2 | c.*1683A>G | 3'UTR (SNP) | VAF 54/99 reads (55%) | called by muse, mutect2, varscan2
- TP53I3 | c.-270_-266del | 5'UTR (DEL) | VAF 50/149 reads (34%) | called by mutect2, pindel, varscan2
- UBXN2B | c.*264G>T | 3'UTR (SNP) | VAF 24/90 reads (27%) | catalogued as rs1020104649; called by muse, mutect2, varscan2
- USH2A | c.*1195C>T | 3'UTR (SNP) | VAF 28/78 reads (36%) | called by muse, mutect2, varscan2
- YIPF2 | c.192+39G>A | Intron (SNP) | VAF 36/128 reads (28%) | catalogued as rs552085351; called by muse, varscan2
- ZNF780A | chr19:40071552 del ATTCAATCCACAGCTAAA | 3'Flank (DEL) | VAF 28/99 reads (28%) | called by mutect2, pindel, varscan2
- ZNF816 | c.64-468T>C | Intron (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
